Gene-level copy-number profile of tumor specimen TCGA-85-8584-01A from TCGA case TCGA-85-8584, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.4 years (26,081 days).
Specimen TCGA-85-8584-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0c75b270-d089-44a2-ab9b-9c4c79a6d814.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8584-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 404 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b29234c2-4828-430c-ae5d-948af03bc1f1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,515; copy number 1: 10,054; copy number 2: 41,229; copy number 3: 4,579; copy number 4: 988; copy number 5: 134; copy number 6: 140; copy number 7: 166; copy number 8: 6; copy number 9: 58; copy number 10: 5; copy number 12: 6; copy number 13: 78; copy number 14: 6; copy number 16: 33; copy number 17: 120; copy number 18: 16; copy number 20: 86.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8584-01A-11D-2391-01): tumor purity 0.39, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 128 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:710,355–784,729, 3 genes (within-gene range 0–3): ZDHHC11B, BRD9P2, AC026740.2.
- chr5:178,825,382–178,842,235, 3 genes: AC126915.2, AC126915.1, AC126915.3.
- chr7:18,892,096–18,899,433, 1 gene: HDAC9-AS1.
- chr8:39,314,591–39,730,065, 4 genes (within-gene range 0–3): ADAM5, ADAM3A, AC123767.1, ADAM18.
- chr9:20,331,446–23,956,444, 80 genes (broad region; genes not listed).
- chr12:7,812,512–7,972,759, 10 genes (within-gene range 0–1): SLC2A14, AC006517.2, Y_RNA, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6.
- chr12:10,824,960–11,171,608, 1 gene (within-gene range 0–7): PRH1.
- chr12:10,845,849–11,171,600, 1 gene (within-gene range 0–7): AC018630.4.
- chr12:10,907,926–11,395,566, 23 genes: TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4, PRB1.
- chr18:59,459,072–59,465,682, 1 gene: AC016229.1.
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 854 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 9 (within-gene range 2–9): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 9: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr12:66,767–4,851,927, 119 genes, copy number 6–7 (within-gene range 1–7) (broad region; genes not listed).
- chr12:8,032,716–9,037,244, 60 genes, copy number 6 (within-gene range 1–6): FOXJ2, C3AR1, NECAP1, AC006511.3, AC006511.5, CLEC4A, POU5F1P3, AC092111.3, GCSHP4, ZNF705A, FAM66C, DEFB109F, AC092111.2, AC092111.1, FAM90A1, ALG1L10P, FAM86FP, LINC02449, AC092745.5, ENPP7P5, AC092745.4, LINC00937, AC092745.2, AC092745.1, AC092745.3, RPS3AP43, AC092865.4, AC092865.3, AC092865.2, OR7E140P, OR7E148P, OR7E149P, CLEC6A, AC092865.1, RNU6-275P, CLEC4D, SUPT4H1P2, CLEC4E, AC092746.1, Y_RNA, AC092184.1, AICDA, AC092184.2, HADHAP2, MFAP5, AC092490.2, AC092490.3, RIMKLB, RPSAP51, A2ML1-AS1, AC092490.1, A2ML1-AS2, A2ML1, AC006581.2, PHC1, M6PR, KLRG1, AC006581.1, HNRNPA1P34, VDAC2P2.
- chr12:10,358,464–10,361,045, 1 gene, copy number 7: LINC02598.
- chr12:10,699,089–10,810,168, 6 genes, copy number 7: YBX3, LINC02366, HSPE1P12, TAS2R7, TAS2R8, TAS2R9.
- chr12:10,825,317–10,849,475, 3 genes, copy number 7: TAS2R10, AC006518.1, PRR4.
- chr12:10,894,943–10,896,952, 1 gene, copy number 7: AC006518.2.
- chr12:15,620,134–17,167,790, 22 genes, copy number 5–18: EPS8, RNU6-251P, AC073651.1, AC073651.2, STRAP, DERA, EGLN3P1, SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1, SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40.
- chr12:19,404,045–19,720,801, 1 gene, copy number 5 (within-gene range 2–5): AEBP2.
- chr12:19,456,244–20,109,893, 8 genes, copy number 5: EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1.
- chr12:20,810,702–33,455,452, 246 genes, copy number 9–20 (broad region; genes not listed).
- chr12:67,424,272–74,402,600, 116 genes, copy number 8–16 (within-gene range 1–16) (broad region; genes not listed).
- chr12:105,173,297–111,403,310, 138 genes, copy number 5–12 (within-gene range 1–12) (broad region; genes not listed).
- chr14:105,836,765–106,309,666, 88 genes, copy number 7 (broad region; genes not listed).
- chr19:19,623,655–19,894,674, 20 genes, copy number 5 (within-gene range 4–5): LPAR2, GMIP, ATP13A1, ZNF101, AC011458.2, AC011458.1, ZNF14, AC011477.6, AC011477.7, AC011477.5, LINC00663, AC011477.8, AC011477.3, AC011477.4, ZNF56, ZNF506, AC011477.1, BNIP3P9, ZNF253, BNIP3P10.

Autosomal genes at a single copy (total copy number 1): 10,054. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
